Somatic mutation profile of tumor specimen C3L-00465-54 (aliquot CPT0055020002) from CPTAC case C3L-00465, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 68.6 years (25,056 days).
Specimen C3L-00465-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc9c783f-5627-4d73-99dd-8b10dfc04e68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00465-52 (Buccal Cell Normal), aliquot CPT0055070005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b36b341-2c13-4b0b-ba0b-a60e7cc5f54b

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Nonsense Mutation 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GFI1B | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 186/373 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554724691, COSV59745290; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OPCML | c.947C>A p.A316E | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1307397497; called by muse, mutect2, varscan2
- BCORL1 | c.4899_4902delinsAAGGTGGGG p.L1634Rfs*35 | Frame Shift Ins (INS) | VAF 35/51 reads (69%) | called by pindel, varscan2*
- CDH9 | c.1033_1034insAGGG p.L345* | Nonsense Mutation (INS) | VAF 28/136 reads (21%) | called by mutect2, pindel
- FAM230J | n.859C>T | RNA (SNP) | VAF 8/42 reads (19%) | catalogued as rs374516211; called by muse, varscan2
